Somatic mutation profile of tumor specimen TARGET-30-PASXNN-01A (aliquot TARGET-30-PASXNN-01A-01D) from TARGET case TARGET-30-PASXNN, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 9.9 years (3,598 days).
Specimen TARGET-30-PASXNN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 816b7069-3352-4f39-9d64-9341acad2bab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASXNN-10A (Blood Derived Normal), aliquot TARGET-30-PASXNN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a099e33b-2f3f-4707-9b7b-626144724549

The open-access MAF lists 59 somatic variants for this specimen: 39 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 35, Silent 20, Frame Shift Del 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAA2 | c.41G>C p.R14P | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53271725; called by muse, mutect2
- ATP8B3 | c.1120C>A p.L374M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as COSV59540818; called by muse, mutect2, varscan2
- CCR2 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1439242955; called by muse, mutect2
- DENND1C | c.1417T>C p.S473P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs760807759, COSV57567934; called by muse, mutect2
- DLG5 | c.3668C>G p.P1223R | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV64947093; called by muse, mutect2
- FANCG | c.1603C>G p.Q535E | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV62719830; called by muse, mutect2, varscan2
- FLG | c.6343C>A p.Q2115K | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as rs1168517932, COSV64237943; called by muse, mutect2, varscan2
- FZD2 | c.1318C>G p.R440G | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59528279; called by muse, mutect2, varscan2
- GART | c.2806G>A p.V936I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); catalogued as rs1313936760, COSV67818156; called by muse, mutect2, varscan2
- GSTM5 | c.315G>T p.M105I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV56656743; called by mutect2, varscan2
- IFNE | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as rs1433398629; called by muse, mutect2, varscan2
- MLXIPL | c.2488A>T p.T830S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.257); catalogued as COSV57667136; called by muse, mutect2, varscan2
- NBEAL1 | c.5321G>T p.R1774L | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101495681; called by muse, mutect2
- OR12D2 | c.188A>T p.N63I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV65826676; called by muse, mutect2, varscan2
- OR5L1 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as COSV61733014; called by muse, mutect2, varscan2
- PSG6 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51830753; called by muse, mutect2, varscan2
- PTPRB | c.3130C>G p.P1044A | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV54234706, COSV54257428; called by muse, mutect2, varscan2
- RPS25 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV57722272; called by muse, mutect2, varscan2
- SGMS2 | c.956del p.Y319Ffs*81 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as COSV62988888; called by mutect2, pindel, varscan2
- SLC35G6 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100262472, COSV59489972; called by muse, varscan2
- SLC6A16 | c.67T>A p.S23T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV60027191; called by muse, mutect2, varscan2
- SNTB1 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1211817777, COSV67324949; called by muse, mutect2, varscan2
- SVEP1 | c.1351T>A p.C451S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57030941; called by muse, mutect2, varscan2
- SYT17 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as COSV62545383; called by muse, mutect2, varscan2
- TTC5 | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV51870358; called by muse, mutect2, varscan2
- TTN | c.97487C>A p.P32496Q (on ENST00000591111; = p.P25072Q on NM_003319.4) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | PolyPhen probably damaging (0.961); catalogued as COSV59919700; called by muse, mutect2, varscan2
- UGT2A3 | c.657C>A p.H219Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV52359100; called by muse, mutect2, varscan2
- WDR76 | c.1824G>T p.L608F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV55476822; called by muse, mutect2, varscan2
- WNK1 | c.5815C>A p.Q1939K (on ENST00000315939 / NM_018979.4; = p.Q1691K on NM_014823.3) | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV60027259; called by muse, mutect2, varscan2
- ZNF594 | c.2224T>A p.F742I | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV68384823; called by muse, mutect2, varscan2
- CAMKK2 | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- COA8 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- GPANK1 | c.899del p.S300* | Frame Shift Del (DEL) | VAF 79/382 reads (21%) | called by mutect2, pindel, varscan2
- KMT2C | c.10915G>T p.E3639* | Nonsense Mutation (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- OR11H1 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.142); called by mutect2, varscan2
- OR14A16 | c.859T>A p.Y287N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RP1 | c.4993C>A p.Q1665K | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2
- SLC17A6 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TSKS | c.588C>A p.C196* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2, varscan2
- CCDC6 | c.387C>A p.T129= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV54055119; called by muse, mutect2, varscan2
- CPED1 | c.321C>T p.Y107= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV59998347; called by muse, mutect2, varscan2
- DENND1A | c.492C>A p.P164= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV65323296; called by muse, mutect2, varscan2
- FLG2 | c.3420C>A p.G1140= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as COSV66168775; called by muse, mutect2
- IGLV1-44 | c.192C>A p.P64= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- IL20RA | c.204T>A p.T68= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV57356725; called by muse, mutect2, varscan2
- LAMA5 | c.9609C>T p.Y3203= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs756426753, COSV53352950; called by muse, mutect2, varscan2
- LINGO2 | c.1659G>T p.L553= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV58057856; called by muse, mutect2, varscan2
- LRRK1 | c.693C>A p.P231= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV52604037; called by muse, varscan2
- MC2R | c.219C>A p.G73= | Silent (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2, varscan2
- NEDD4L | c.696G>A p.E232= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV56841415; called by muse, mutect2, varscan2
- OR4L1 | c.288C>A p.G96= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV59849100; called by muse, mutect2, varscan2
- PAX1 | c.1107C>A p.A369= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV68271253; called by muse, mutect2, varscan2
- PHEX | c.1953G>T p.R651= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV65074169; called by muse, mutect2, varscan2
- PLXNA3 | c.2569C>A p.R857= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV100859779, COSV63753389; called by muse, mutect2, varscan2
- RNF213 | c.8709C>A p.G2903= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV60392047; called by muse, mutect2, varscan2
- SNAPC4 | c.762G>T p.L254= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- STK10 | c.291G>T p.L97= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV51571126; called by muse, mutect2, varscan2
- TET3 | c.1011G>T p.L337= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV59880321; called by muse, mutect2, varscan2
- ZFPM2 | c.987G>T p.L329= | Silent (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
